Gene-level copy-number profile of tumor specimen TCGA-AA-A00F-01A from TCGA case TCGA-AA-A00F, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.7 years (24,379 days).
Specimen TCGA-AA-A00F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e170d3aa-71a8-44d0-a049-ad91538efb21.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A00F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62950bdc-ee79-4bb0-aeed-3d6dd85c5ac9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,245; copy number 2: 21,126; copy number 3: 20,603; copy number 4: 9,287; copy number 5: 4,055; copy number 6: 669; copy number 7: 871; copy number 8: 84; copy number 9: 321.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-A00F-01): tumor purity 0.45, ploidy 3.14, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,000 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:63,423,596–63,550,051, 1 gene, copy number 5 (within-gene range 4–5): SYNPR-AS1.
- chr5:1,173,141–2,788,549, 42 genes, copy number 5: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, AC026412.4, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1.
- chr5:13,144,000–13,190,677, 1 gene, copy number 5: AC016553.1.
- chr5:14,664,664–16,033,356, 19 genes, copy number 6 (within-gene range 3–6): OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178.
- chr5:38,429,892–39,572,639, 19 genes, copy number 5–7: AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1.
- chr6:166,319,728–170,738,536, 110 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 5 (within-gene range 5–6) (broad region; genes not listed).
- chr11:65,695,552–65,797,219, 9 genes, copy number 7: RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1.
- chr11:95,571,040–107,316,271, 135 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:66,767–7,503,893, 230 genes, copy number 5 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5–9 (broad region; genes not listed).
- chr14:105,764,503–106,344,833, 98 genes, copy number 6 (broad region; genes not listed).
- chr20:25,919,499–64,313,132, 931 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 858. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
